Somatic mutation profile of tumor specimen TCGA-AG-3898-01A (aliquot TCGA-AG-3898-01A-01W-1073-09) from TCGA case TCGA-AG-3898, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-AG-3898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd91f540-4a1d-4618-a2fa-37e57ddcff2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3898-10A (Blood Derived Normal), aliquot TCGA-AG-3898-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b87a79-950c-4f1e-9bae-3bb481f8a49c

The open-access MAF lists 122 somatic variants for this specimen: 85 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 33, Nonsense Mutation 4, Splice Site 3, 3'UTR 2, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754201976, CD942043, CM910043, CM930035, COSV65960551; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 1191/1245 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 130/201 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADH7 | c.381C>T p.S127= | Splice Region (SNP) | VAF 33/184 reads (18%) | catalogued as rs141541308, COSV52922179; called by muse, mutect2, varscan2
- APC | c.3121C>G p.Q1041E | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as CM920045, COSV57346121, COSV57364346; called by muse, mutect2, varscan2
- APC | c.4280del p.P1427Lfs*46 | Frame Shift Del (DEL) | VAF 33/135 reads (24%) | catalogued as COSV57384647; called by mutect2, pindel, varscan2
- ARHGAP36 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs931500314, COSV52269582, COSV99357785; called by muse, mutect2, varscan2
- ASAP1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 196/480 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100727267; called by mutect2, varscan2
- ATAD2B | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs767001795, COSV53202862; called by muse, mutect2, varscan2
- ATP2B1 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV99666229; called by muse, mutect2
- CCT8L2 | c.633dup p.T212Dfs*52 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs767593972; called by mutect2, pindel, varscan2
- CDH12 | c.2286C>A p.D762E | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66427475; called by muse, mutect2, varscan2
- CDH9 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535692550, COSV50266744; called by muse, mutect2, varscan2
- CDHR2 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs749597145, COSV56142351; called by muse, mutect2, varscan2
- CEP170 | c.2488T>A p.S830T | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV100317968; called by muse, mutect2, varscan2
- CEP170 | c.2241A>T p.K747N | Missense Mutation (SNP) | VAF 179/569 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV60511778; called by muse, mutect2, varscan2
- CEP290 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58354076; called by muse, mutect2, varscan2
- CES5A | c.915+1G>C p.X305_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as rs1467290727, COSV99308081; called by muse, varscan2
- CFAP44 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs370318076; called by muse, mutect2, varscan2
- CFHR5 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 105/279 reads (38%) | catalogued as COSV56825131, COSV56829246; called by muse, mutect2, varscan2
- CNKSR2 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV54261892; called by muse, mutect2, varscan2
- CSMD3 | c.7777C>A p.R2593S (on ENST00000297405 / NM_001363185.1; = p.R2489S on NM_052900.3) | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52164475, COSV52212859; called by muse, mutect2, varscan2
- CSMD3 | c.4312A>G p.N1438D (on ENST00000297405 / NM_001363185.1; = p.N1334D on NM_052900.3) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52254603; called by muse, mutect2, varscan2
- CUBN | c.9154G>T p.A3052S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV64722256; called by muse, mutect2, varscan2
- DAW1 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59366227; called by muse, mutect2, varscan2
- ERAP2 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65940722; called by muse, mutect2, varscan2
- FADS2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs778333968, COSV53900675; called by muse, mutect2, varscan2
- FAM167A | c.614A>T p.N205I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52670145; called by muse, mutect2, varscan2
- FAM184A | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.727); catalogued as rs745898811, COSV58856568; called by muse, mutect2, varscan2
- FLRT3 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54019756; called by muse, varscan2
- GPX3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs771337658, COSV59308895; called by muse, mutect2, varscan2
- GRIA4 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV56909598; called by muse, mutect2, varscan2
- HDHD5 | c.555C>G p.D185E (on ENST00000336737 / NM_033070.3; = p.D155E on NM_017829.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1459480899, COSV50089594; called by muse, mutect2, varscan2
- HSPA6 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.426); catalogued as rs750741969, COSV59061446; called by muse, mutect2
- IL17RD | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1230169111, COSV56340957; called by muse, mutect2, varscan2
- IL1RN | c.496G>A p.V166I (on ENST00000409930 / NM_173842.3; = p.V148I on NM_000577.5) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs143208167; called by muse, mutect2
- KMT2C | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 58/670 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100074955; called by muse, mutect2
- LHPP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as rs774113542, COSV64330535; called by muse, mutect2, varscan2
- LRBA | c.7055G>A p.R2352H | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371873204; called by muse, mutect2, varscan2
- LRCH1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60850598; called by muse, mutect2, varscan2
- MAP3K21 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64045701; called by muse, mutect2, varscan2
- MAP7 | c.989+1G>T p.X330_splice | Splice Site (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100644046; called by muse, mutect2, varscan2
- METTL21A | c.261T>A p.G87= | Splice Region (SNP) | VAF 6/118 reads (5%) | catalogued as COSV99777790; called by muse, mutect2
- MKRN3 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV58811128, COSV58811410; called by muse, mutect2, varscan2
- MRM2 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54248716; called by muse, mutect2, varscan2
- MTUS1 | c.2450C>A p.S817Y | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV50571186; called by muse, mutect2, varscan2
- NEK8 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs1323633715, COSV52047126, COSV52047400; called by muse, mutect2, varscan2
- NTNG2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1430653423, COSV62364447; called by muse, mutect2, varscan2
- OR1C1 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.407); catalogued as COSV68716041; called by muse, mutect2, varscan2
- OR2AG2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs569276635, COSV58455025; called by muse, mutect2, varscan2
- PCDH19 | c.3007G>A p.E1003K (on ENST00000373034 / NM_001184880.2; = p.E955K on NM_020766.3) | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1018781176, COSV55267889; called by muse, mutect2, varscan2
- PCDHB3 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV50600078; called by muse, mutect2, varscan2
- POLA1 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66889016; called by muse, varscan2
- PPM1B | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56764965, COSV56765756; called by muse, mutect2, varscan2
- PRKD1 | c.2397G>A p.M799I | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100121714; called by muse, mutect2
- PUM1 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57088943; called by muse, mutect2
- RNF133 | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57375391; called by muse, mutect2, varscan2
- RNF19B | c.934T>A p.C312S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52389135; called by muse, mutect2, varscan2
- RNF7 | c.224-2A>G p.X75_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99858025; called by muse, mutect2, varscan2
- RNPS1 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57047314; called by muse, mutect2, varscan2
- RPL13A | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV99201368; called by muse, mutect2
- RTL3 | c.705T>G p.D235E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58184992; called by muse, mutect2, varscan2
- SEMA6D | c.3044C>A p.T1015K (on ENST00000316364 / NM_153618.2; = p.T953K on NM_020858.2) | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60381044; called by muse, mutect2, varscan2
- SLC38A1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67064216; called by muse, mutect2
- SLIT2 | c.4406C>T p.A1469V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99887696; called by muse, mutect2
- STPG2 | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV54810314; called by muse, varscan2
- TATDN2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 76/260 reads (29%) | catalogued as rs771509725, COSV55053080; called by muse, mutect2, varscan2
- TCAF2 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV62052008; called by muse, mutect2, varscan2
- TCF7L2 | c.685G>A p.G229R (on ENST00000355995 / NM_001367943.1; = p.G206R on NM_030756.5) | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53340767; called by muse, mutect2, varscan2
- TLE4 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99513332; called by muse, mutect2
- TMPO | c.1706T>G p.L569R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54124393; called by muse, mutect2, varscan2
- TP53 | c.951_954dup p.K319Afs*19 | Frame Shift Ins (INS) | VAF 33/72 reads (46%) | catalogued as COSV53686610; called by mutect2, varscan2
- TP53I3 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as rs1253572520, COSV53188386; called by muse, mutect2, varscan2
- TRPC3 | c.1880C>T p.A627V (on ENST00000379645 / NM_001366479.2; = p.A554V on NM_003305.2) | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV53378460; called by muse, mutect2, varscan2
- TRPC7 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397312641, COSV61454306; called by muse, mutect2, varscan2
- TUBA4A | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.522); catalogued as COSV50279876; called by muse, mutect2, varscan2
- USP10 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 133/427 reads (31%) | catalogued as COSV54746672; called by muse, mutect2, varscan2
- USP39 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143344250; called by muse, mutect2, varscan2
- WASHC5 | c.862T>G p.W288G | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59198836; called by muse, mutect2, varscan2
- YTHDF1 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64833522; called by muse, mutect2, varscan2
- ZC3HAV1 | c.388A>C p.N130H | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54298827; called by muse, mutect2, varscan2
- ZNF415 | c.351T>A p.N117K | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV54703383; called by muse, mutect2, varscan2
- ZNF875 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs761515101, COSV60990924; called by muse, mutect2, varscan2
- PNISR | c.992_993del p.E331Vfs*21 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by pindel, varscan2
- ABCA4 | c.5721C>T p.A1907= | Silent (SNP) | VAF 44/200 reads (22%) | catalogued as rs368502305; called by muse, mutect2
- ACAD9 | c.1407G>A p.R469= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV58307152, COSV58308993; called by muse, mutect2, varscan2
- ADGRF1 | c.66G>A p.L22= | Silent (SNP) | VAF 69/208 reads (33%) | catalogued as rs149265399; called by muse, mutect2, varscan2
- ARHGEF7 | c.1228C>T p.L410= (on ENST00000375741 / NM_001113511.2; = p.L232= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV54547783; called by muse, mutect2, varscan2
- ATP10A | c.2754C>A p.T918= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV63520837, COSV63521520; called by muse, mutect2, varscan2
- DYNC2I1 | c.582C>T p.Y194= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as rs368847195; called by muse, mutect2, varscan2
- EVA1A | c.354G>A p.L118= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV99285946; called by muse, mutect2
- FAM47A | c.2292T>G p.T764= | Silent (SNP) | VAF 25/370 reads (7%) | catalogued as COSV100649725, COSV60493933; called by muse, mutect2
- FEM1C | c.1095G>A p.L365= | Silent (SNP) | VAF 43/226 reads (19%) | catalogued as COSV57232299; called by muse, mutect2, varscan2
- FOXS1 | c.180C>T p.P60= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as rs1046363373, COSV54066626; called by muse, mutect2
- FTMT | c.369C>T p.T123= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1270133886, COSV58420900; called by muse, mutect2, varscan2
- HSP90AB1 | c.1377C>A p.T459= | Silent (SNP) | VAF 104/325 reads (32%) | catalogued as COSV62335709; called by muse, mutect2, varscan2
- IGSF10 | c.6180C>T p.C2060= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs761874663, COSV56388502; called by muse, mutect2, varscan2
- IRAK1BP1 | c.327A>T p.I109= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV64048595; called by muse, mutect2, varscan2
- KAT14 | c.2049C>T p.V683= | Silent (SNP) | VAF 62/583 reads (11%) | catalogued as COSV66608590; called by muse, mutect2
- KCNA6 | c.687C>T p.D229= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as rs781694280, COSV54976496; called by muse, mutect2, varscan2
- LASP1 | c.711C>T p.D237= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs746197131, COSV58803016; called by mutect2, varscan2
- MUC16 | c.12303C>T p.G4101= | Silent (SNP) | VAF 87/275 reads (32%) | catalogued as rs772443215, COSV67480603; called by muse, mutect2, varscan2
- NDUFA10 | c.312C>T p.L104= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs145407882; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR1C1 | c.810C>T p.S270= | Silent (SNP) | VAF 71/150 reads (47%) | catalogued as rs746047503, COSV68715354; called by muse, mutect2, varscan2
- PCDH1 | c.3531C>T p.D1177= | Silent (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
- PCDHGA9 | c.1599G>A p.T533= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs764332245, COSV53943574, COSV99544430; called by muse, mutect2, varscan2
- PKIB | c.48C>T p.A16= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV99236690; called by muse, mutect2
- PNLIPRP3 | c.744C>T p.H248= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV65049054; called by muse, mutect2, varscan2
- QRICH1 | c.969G>A p.Q323= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV62617687; called by muse, mutect2
- RNF130 | c.780C>T p.D260= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs145652271; called by muse, mutect2, varscan2
- SHROOM2 | c.720C>A p.G240= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV66609046; called by muse, mutect2
- TASP1 | c.918T>C p.C306= | Silent (SNP) | VAF 140/365 reads (38%) | catalogued as COSV61814634; called by muse, mutect2, varscan2
- TLL2 | c.1377G>A p.A459= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs750004312, COSV63573275; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3861G>A p.L1287= | Silent (SNP) | VAF 220/451 reads (49%) | catalogued as COSV64101869; called by muse, mutect2, varscan2
- ZFHX4 | c.9000C>T p.G3000= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs1183735569, COSV50565031; called by muse, mutect2, varscan2
- ZNF578 | c.546G>A p.K182= | Silent (SNP) | VAF 144/396 reads (36%) | catalogued as COSV69737133; called by muse, mutect2, varscan2
- ZNF630 | c.1467T>C p.C489= | Silent (SNP) | VAF 21/193 reads (11%) | catalogued as COSV52097560; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850099 C>A | 5'Flank (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+18_2176+41delinsCCAAGCCAGGGTGGGCGGGGGG | Intron (DEL) | VAF 3/30 reads (10%) | called by pindel, varscan2*
- TAFA4 | c.*1C>T | 3'UTR (SNP) | VAF 36/167 reads (22%) | catalogued as rs767390441, COSV55144757; called by muse, mutect2, varscan2
- XIRP2 | c.*558G>A | 3'UTR (SNP) | VAF 10/204 reads (5%) | catalogued as COSV54688060, COSV54719424; called by muse, mutect2
